Somatic mutation profile of tumor specimen 0DRQT2 from CCDI case PBCGYU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.2 years (1,165 days).
Specimen 0DRQT2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1b4cf68-53a2-4a58-b7e2-45f1ba74e7fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRQSQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e41dc75f-de2b-49e1-bd9c-d3881fc95685

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'Flank 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH8 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 16/542 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100109789; called by muse, mutect2
- POGK | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.916); catalogued as rs776736387; called by muse, mutect2
- TOGARAM1 | c.1570C>A p.R524S | Missense Mutation (SNP) | VAF 31/1018 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61889208; called by muse, mutect2
- RBP3 | c.2472G>A p.W824* | Nonsense Mutation (SNP) | VAF 33/280 reads (12%) | called by muse, mutect2, varscan2
- USP26 | c.1734G>T p.K578N | Missense Mutation (SNP) | VAF 308/850 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF770 | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 36/995 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- PGK1 | c.286T>C p.L96= | Silent (SNP) | VAF 37/1382 reads (3%) | called by muse, mutect2
- TNRC18 | chr7:5428075 G>A | 5'Flank (SNP) | VAF 19/416 reads (5%) | called by muse, mutect2
